Surgical pathology report (de-identified scan), TCGA case TCGA-DW-7841, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site NCI Urologic Oncology Branch, specimen TCGA-DW-7841-01A (Primary Tumor).

[page 1 of 3]
DIAGNOSIS:

1. Kidney, left tumor #1, biopsy: Papillary renal cell carcinoma, type I.
2. Kidney, left tumor #2, biopsy: Papillary renal cell carcinoma, type I.
3. Kidney, left tumor #3, biopsy: Cystic dilatation and sclerotic renal parenchyma, no tumor seen.
4. Kidney, left tumor #4, biopsy:
- Papillary renal cell carcinoma, type 1.
- Renal parenchyma with chronic interstitial nephritis and hyalinization of the glomeruli.
5. Kidney, left tumor #5, biopsy: Renal parenchyma with incipient lesion and renal cyst.
6. Kidney, left tumor #6, biopsy: Renal parenchyma with sclerotic changes.
7. Kidney, left tumor #7, biopsy: Renal cyst.

NOTE: Immunohistochemical studies of specimen #4 with cytokeratin 7 and calretinin demonstrate a focus of tumor cells in the adjacent fat.

[page 2 of 3]
[REDACTED]

[REDACTED]

CLINICAL INFORMATION: Allocate Order to [REDACTED] Brief Clinical History:
bilateral renal tumors with outside renal biopsy showing papillary
type I RCC Specimen Taken For [REDACTED]

PROCEDURE: Pre-Operative Diagnosis: left renal tumors Post-Operative Diagnosis:
left renal tumors Operative Findings: 7 left renal tumors and cysts
removed

SPECIMENS SUBMITTED: 1. TUMOR, Left renal # 1
2. TUMOR, Left renal # 2
3. TUMOR, Left renal # 3
4. TUMOR, Left renal # 4
5. TUMOR, Left renal # 5
6. TUMOR, Left renal # 6
7. TUMOR, Left kidney # 7

GROSS DESCRIPTION: Received fresh in containers labeled with patient's name, medical record number,
and specified as follows are:

1. "Left kidney tumor #1". It is a tan mass measuring 2.5 x 2.5 x 2 cm. The cut surface is tan to yellow with a focal area of hemorrhage. 50% of the tumor is procured for [REDACTED] The specimen is received in Pathology and matches the above description. The specimen is bisected and entirely submitted in white cassettes labeled [REDACTED] #1A and #1B.
2. "Left kidney tumor #2". It is a tan mass measuring 2 x 1.5 x 1.4 cm with a tan to yellow cut surface. 50% is procured for [REDACTED] The specimen is received in Pathology and matches the above description. The specimen is bisected and entirely submitted in a white cassette labeled #2.
3. "Left renal tumor #3". It is a tan to yellow soft tissue fragment measuring 1 x 0.7 x 0.4 cm. 50% of tissue is procured for [REDACTED] The specimen is received in Pathology and matches the above description. The specimen is entirely submitted in a white cassette labeled #3.
4. "Left kidney tumor #4". It consists of a tan mass measuring 5 x 5 x 4 cm with a tan to yellow homogeneous cut surface. 50% of the tumor is procured for [REDACTED] Additional tan to red fibrous soft

Patient Identification

[REDACTED]

[page 3 of 3]
tissue measuring 5 x 2.5 x 2 cm is also included in the container. The specimen is received in Pathology and matches the above description. Representative sections from the mass from which procurement took place are taken and placed into white cassettes labeled 4A-4C. Representative sections from the additional fibrous tissue are taken and placed into white cassettes labeled 4D and 4E.

5. "Left kidney tumor #5". It consists of tan soft tissue fragments measuring 1.7 x 1.7 x 0.6 cm. 50% of tissue is procured for [REDACTED]. The specimen is received in Pathology and matches the above description. It is entirely submitted in white cassettes labeled 5A and 5B.
6. "Left kidney tumor #6". It consists of yellow to tan soft tissue fragments measuring 0.4 x 0.2 x 0.1 cm. It is not procured. It is entirely submitted in a white cassette labeled #6.
7. "Left kidney tumor #7". It is a tan soft tissue fragment measuring 0.9 x 0.4 x 0.4 cm. 50% is procured for [REDACTED]. The specimen is received in Pathology and matches the above description. It is entirely submitted in a white cassette labeled #7.

Gross description dictated by [REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

Patient Identification

Source: NCI Genomic Data Commons file fc829e14-a345-4f4a-9172-ebe948a64bc1 (TCGA-DW-7841.DC7FF74C-EDBE-4C70-8892-D85ED1B16E08.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).